Somatic mutation profile of tumor specimen TCGA-14-1037-01A (aliquot TCGA-14-1037-01A-01W-0643-08) from TCGA case TCGA-14-1037, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.9 years (24,426 days).
Specimen TCGA-14-1037-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 203da0ce-c577-41bb-a823-547318ab7360.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1037-10B (Blood Derived Normal), aliquot TCGA-14-1037-10B-01W-0644-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcdfa3d7-efac-4f18-88cc-45a11267278c

The open-access MAF lists 56 somatic variants for this specimen: 43 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 11, Nonsense Mutation 3, Splice Site 2, Intron 2, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.2107-1G>A p.X703_splice | Splice Site (SNP) | VAF 42/79 reads (53%) | catalogued as rs587778860, CS125752, COSV57297199, COSV57304025; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABRAXAS2 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1233255087, COSV100045034; called by muse, mutect2, varscan2
- ADAMTS12 | c.2534G>A p.R845H | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs551278824, COSV61256246; called by muse, mutect2, varscan2
- ADD3 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as COSV53323400; called by muse, mutect2, varscan2
- ADH6 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 150/367 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778701583, COSV52956709; called by muse, mutect2, varscan2
- ATP8A2 | c.1736T>C p.I579T | Missense Mutation (SNP) | VAF 187/440 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs1329254555, COSV54959672; called by muse, mutect2, varscan2
- B3GNT5 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 112/296 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs548273302, COSV58476229; called by muse, mutect2, varscan2
- CACNA1S | c.1453G>A p.G485R | Missense Mutation (SNP) | VAF 172/463 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs375469357; called by muse, mutect2, varscan2
- CNDP1 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs371268412; called by muse, mutect2, varscan2
- CNTN4 | c.2281G>A p.V761M | Missense Mutation (SNP) | VAF 245/692 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs763159501, COSV61871407, COSV61875748; called by muse, mutect2, varscan2
- DAB2 | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs374766869; called by muse, mutect2, varscan2
- DMRTB1 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1444843178, COSV65113050; called by muse, mutect2, varscan2
- EEF1A1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as COSV58548942; called by muse, mutect2, varscan2
- ELMO2 | c.244-1G>A p.X82_splice | Splice Site (SNP) | VAF 6/201 reads (3%) | catalogued as COSV99281830; called by muse, mutect2
- FAM83C | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs149089081, COSV65582447; called by muse, varscan2
- GALNTL5 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.279); catalogued as rs767171250, COSV67180428; called by muse, mutect2, varscan2
- GAS1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.444); catalogued as COSV53927359; called by muse, mutect2, varscan2
- GEMIN5 | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.441); catalogued as COSV53561753; called by muse, mutect2, varscan2
- IFT80 | c.2100G>A p.R700= | Splice Region (SNP) | VAF 27/122 reads (22%) | catalogued as COSV58448958; called by muse, mutect2, varscan2
- IL16 | c.952T>C p.C318R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV57264892; called by muse, mutect2, varscan2
- KCNH4 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52921554; called by muse, mutect2, varscan2
- KIDINS220 | c.3707C>T p.T1236M | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as rs751189236, COSV56755192; called by muse, mutect2, varscan2
- KRT222 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs145393907, COSV67497785; called by muse, mutect2, varscan2
- MCF2L2 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs775278339, COSV61051831; called by muse, mutect2, varscan2
- MORC3 | c.1658A>G p.N553S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV68688592; called by muse, mutect2, varscan2
- NOS1 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 154/433 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1451276089, COSV57610696; called by muse, mutect2, varscan2
- NXF1 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 34/84 reads (40%) | catalogued as COSV53674673; called by muse, mutect2, varscan2
- OR2A5 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101278796; called by muse, mutect2, varscan2
- OR5K3 | c.710C>A p.S237Y | Missense Mutation (SNP) | VAF 148/450 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs749485140, COSV67350242; called by muse, mutect2, varscan2
- PLXNC1 | c.3664_3667del p.V1222Mfs*20 | Frame Shift Del (DEL) | VAF 35/100 reads (35%) | catalogued as rs759208451; called by mutect2, pindel, varscan2
- PPP2R3A | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 477/1204 reads (40%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs548075977, COSV53866223; called by muse, mutect2, varscan2
- RBM6 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 81/226 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV56484446; called by muse, mutect2, varscan2
- SLC6A4 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99911487; called by muse, mutect2, varscan2
- TKTL1 | c.54G>T p.R18S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV54213546; called by muse, mutect2, varscan2
- TSHZ2 | c.2480G>A p.R827H | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as rs112191590; called by muse, mutect2, varscan2
- UGT8 | c.1570C>T p.L524F | Missense Mutation (SNP) | VAF 81/303 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.043); catalogued as rs1290898525, COSV60418768; called by muse, mutect2, varscan2
- WLS | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 165/580 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as COSV52043052; called by muse, mutect2, varscan2
- ZCCHC12 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs946147207, COSV59570945; called by muse, mutect2, varscan2
- ZNF154 | c.686A>T p.K229M | Missense Mutation (SNP) | VAF 29/696 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV101377526; called by muse, mutect2
- ZNF92 | c.368G>T p.C123F (on ENST00000328747 / NM_152626.4; = p.C54F on NM_007139.4) | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV100165883; called by muse, mutect2
- MGAT1 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | PolyPhen possibly damaging (0.769); called by muse, mutect2
- TG | c.5788dup p.D1930Gfs*31 | Frame Shift Ins (INS) | VAF 94/333 reads (28%) | called by mutect2, pindel, varscan2
- XPO1 | c.1116C>G p.Y372* | Nonsense Mutation (SNP) | VAF 5/105 reads (5%) | called by muse, mutect2
- AP1M2 | c.345C>T p.D115= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs369732438; called by muse, mutect2, varscan2
- ASB5 | c.27G>A p.P9= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs769501584, COSV56671998; called by muse, mutect2, varscan2
- DGKE | c.363C>T p.D121= | Silent (SNP) | VAF 37/195 reads (19%) | catalogued as rs759138367, COSV52350239; called by muse, mutect2, varscan2
- GIMAP1 | c.342G>A p.A114= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs754697498, COSV56188736; called by muse, mutect2, varscan2
- IGSF10 | c.1314G>A p.L438= | Silent (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- NLGN1 | c.1419G>A p.A473= | Silent (SNP) | VAF 277/799 reads (35%) | catalogued as rs200258151; called by muse, mutect2, varscan2
- PIK3AP1 | c.396C>T p.T132= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100226015; called by muse, mutect2
- RYR3 | c.8385C>T p.I2795= (on ENST00000389232; = p.I2796= on NM_001036.6) | Silent (SNP) | VAF 45/141 reads (32%) | catalogued as COSV101213234; called by muse, mutect2, varscan2
- SLC8A3 | c.2085C>A p.T695= (on ENST00000381269 / NM_183002.3; = p.T693= on NM_033262.4) | Silent (SNP) | VAF 133/362 reads (37%) | catalogued as COSV53690612; called by muse, mutect2, varscan2
- SVOPL | c.1116G>A p.L372= (on ENST00000419765; = p.L220= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/265 reads (6%) | catalogued as COSV55993987; called by muse, mutect2
- TM4SF5 | c.492C>T p.A164= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as rs773396153, COSV54495999; called by muse, mutect2, varscan2
- KDM4B | c.1115+979G>A | Intron (SNP) | VAF 42/122 reads (34%) | catalogued as rs751348106, COSV99346870; called by muse, mutect2, varscan2
- SLC9A6 | c.429+71T>C | Intron (SNP) | VAF 28/75 reads (37%) | catalogued as COSV65788309; called by muse, varscan2
